Gene-level copy-number profile of tumor specimen TCGA-GV-A3QH-01A from TCGA case TCGA-GV-A3QH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 67.6 years (24,681 days).
Specimen TCGA-GV-A3QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9c44d14a-a271-4da5-a6ff-202a7e79417b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3QH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5834191-e052-4c6d-ad44-3463e2026e92

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 867; copy number 2: 12,949; copy number 3: 30,173; copy number 4: 11,234; copy number 5: 3,899; copy number 6: 209; copy number 7: 156; copy number 8: 112; copy number 9: 54; copy number 10: 2; copy number 14: 49; copy number 16: 19; copy number 20: 37; copy number 23: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3QH-01A-11D-A21Y-01): tumor purity 0.48, ploidy 5.64, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,084,155–75,435,110, 14 genes: NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP.
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:112,950,247–113,167,678, 1 gene (within-gene range 0–2): TCF7L2.
- chr10:112,987,476–112,987,865, 1 gene: RPS15AP30.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 444 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:116,489,364–124,252,044, 109 genes, copy number 8–10 (broad region; genes not listed).
- chr4:143,184,917–147,159,068, 70 genes, copy number 9–14 (broad region; genes not listed).
- chr6:19,638,040–24,666,930, 56 genes, copy number 16–20: UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2.
- chr7:31,941,261–31,941,583, 1 gene, copy number 8: SNX2P2.
- chr17:39,238,466–39,864,312, 19 genes, copy number 8–23 (within-gene range 4–23): AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr22:27,676,559–32,464,484, 189 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 843. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
